Surgical pathology report (de-identified scan), TCGA case TCGA-86-8074, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Asterand, specimen TCGA-86-8074-01A (Primary Tumor).

[page 1 of 2]
TCGA Pathology Reports

Case ID	OpenClinica ID	Gross Description	Microscopic Description	Diagnosis Details	Comments

[page 2 of 2]
Formatted Path
Report

LUNG TISSUE CHECKLIST

Specimen type: Lobectomy
Tumor site: Lung
Tumor size: 2.7 x 2.5 x 2.5
cm
Histologic type: Papillary
adenocarcinoma
Histologic grade:
Moderately differentiated
Tumor extent: Not
specified
Other tumor nodules: Not
specified
Lymph nodes: 5/5 positive
for metastasis
(Intrathoracical 5/5)
Lymphatic invasion: Not
specified
Venous invasion: Not
specified
Margins: Not specified
Evidence of neo-adjuvant
treatment: Not specified
Additional pathologic
findings: Not specified
Comments: None

Laterality

Left-lower

Excision date

Source: NCI Genomic Data Commons file 2c57fbaf-b2aa-4e07-8077-20c97d989ddf (TCGA-86-8074.A1E9569B-0254-4BE6-ADB2-3A842E23613F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).